Somatic mutation profile of cancer-model specimen HCM-BROD-0254-C49-85N (Adherent Cell Line, passage 10; aliquot HCM-BROD-0254-C49-85N-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3da5089c-e1b9-49a5-9283-7e632e4dc10d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0254-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0254-C49-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7c2effa-38b8-4a2c-b215-bf4367d784c5

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPT2 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs74315293, CM920217, COSV53760198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 21/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54351826; called by muse, mutect2
- CCDC168 | c.14248G>A p.E4750K | Missense Mutation (SNP) | VAF 166/340 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV104400384; called by muse, mutect2, varscan2
- CDC42SE1 | c.213G>T p.R71S | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.765); catalogued as COSV61785509; called by muse, mutect2, varscan2
- CLCN1 | c.1895C>A p.T632N | Missense Mutation (SNP) | VAF 60/361 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV100578275; called by muse, mutect2, varscan2
- CYP11B1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs544670837, COSV52824806, COSV52825753; called by muse, mutect2, varscan2
- DGKD | c.2479G>A p.G827R (on ENST00000264057 / NM_152879.3; = p.G783R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/475 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374982750, COSV51095884; called by muse, mutect2, varscan2
- GFPT2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 66/576 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs537515231; called by muse, mutect2, varscan2
- LPP | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs768610065; called by muse, mutect2, varscan2
- NOTCH4 | c.4907C>T p.T1636I | Missense Mutation (SNP) | VAF 167/654 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66682790; called by mutect2, varscan2
- PIK3R2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 155/600 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs773024898, COSV53226279; called by muse, mutect2, varscan2
- RHEX | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.367); catalogued as COSV58982138; called by muse, mutect2, varscan2
- SENP7 | c.3068G>C p.R1023P | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58607948; called by muse, mutect2, varscan2
- TMEM63B | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 145/466 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52482334; called by muse, mutect2, varscan2
- ABCA10 | c.3752T>C p.M1251T | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADH4 | c.1038C>A p.F346L | Missense Mutation (SNP) | VAF 151/224 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGDIA | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 111/562 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMK2G | c.1276C>T p.R426* (on ENST00000423381 / NM_001367518.1; = p.R363* on NM_001222.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 104/428 reads (24%) | called by muse, mutect2, varscan2
- DNAJC13 | c.2156del p.V719Gfs*5 | Frame Shift Del (DEL) | VAF 31/232 reads (13%) | called by mutect2, pindel, varscan2
- DNMT3B | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 79/618 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM13B | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FANCD2 | c.4343G>A p.S1448N | Missense Mutation (SNP) | VAF 17/385 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- FURIN | c.2312G>A p.C771Y | Missense Mutation (SNP) | VAF 72/794 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.129); called by muse, mutect2
- GRID1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 78/609 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HDGF | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 58/608 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- ITPR3 | c.5362_5364delinsTT p.V1788Ffs*6 | Frame Shift Del (DEL) | VAF 129/515 reads (25%) | called by pindel, varscan2*
- KANK3 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 207/766 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- LAMB4 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- LYST | c.5654G>C p.C1885S | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- MAPRE3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 89/411 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MYO7A | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 97/678 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- OR4A8 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 72/378 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PER3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCQ | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 57/444 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK6 | c.681_682dup p.H228Rfs*13 | Frame Shift Ins (INS) | VAF 72/587 reads (12%) | called by mutect2, pindel, varscan2
- RTL1 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 125/462 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SCARF2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 138/583 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.176); called by muse, varscan2
- SERPINB4 | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SGIP1 | c.647-14_668del p.X216_splice | Splice Site (DEL) | VAF 26/244 reads (11%) | called by mutect2, pindel, varscan2
- SLC45A2 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 579/581 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLCO2B1 | c.150dup p.F51Vfs*100 | Frame Shift Ins (INS) | VAF 64/496 reads (13%) | called by mutect2, pindel, varscan2
- TLN1 | c.6754G>T p.D2252Y | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TMC5 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMCC2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNRC6C | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 77/471 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TRIM49 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 60/411 reads (15%) | called by muse, mutect2, varscan2
- UMPS | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AC092835.1 | c.765T>C p.G255= | Silent (SNP) | VAF 19/477 reads (4%) | called by muse, mutect2
- ALDH1A1 | c.564C>T p.N188= | Silent (SNP) | VAF 62/297 reads (21%) | called by muse, mutect2, varscan2
- B3GNT7 | c.999C>T p.C333= | Silent (SNP) | VAF 132/886 reads (15%) | called by muse, mutect2, varscan2
- BCOR | c.3867C>T p.G1289= (on ENST00000378444 / NM_001123385.2; = p.G1255= on NM_017745.6) | Silent (SNP) | VAF 80/186 reads (43%) | called by muse, mutect2, varscan2
- BPTF | c.4149G>C p.V1383= | Silent (SNP) | VAF 55/653 reads (8%) | called by muse, mutect2
- CATSPERG | c.2601G>A p.G867= | Silent (SNP) | VAF 73/301 reads (24%) | catalogued as COSV53051110; called by muse, mutect2, varscan2
- CBX6 | c.1053C>T p.S351= | Silent (SNP) | VAF 354/553 reads (64%) | catalogued as rs775494009, COSV99328049; called by muse, mutect2, varscan2
- CYP11B1 | c.69A>G p.A23= | Silent (SNP) | VAF 66/498 reads (13%) | called by muse, mutect2, varscan2
- CYP4F3 | c.714G>A p.Q238= | Silent (SNP) | VAF 71/274 reads (26%) | catalogued as rs1406106262, COSV99658148; called by muse, mutect2, varscan2
- HDGF | c.282T>G p.T94= | Silent (SNP) | VAF 58/615 reads (9%) | catalogued as rs768735820; called by muse, mutect2
- LPIN2 | c.1452A>G p.S484= | Silent (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- MGAM | c.5490G>A p.T1830= | Silent (SNP) | VAF 88/326 reads (27%) | catalogued as rs752684574, COSV72073855; called by muse, mutect2, varscan2
- OR2L2 | c.888G>T p.V296= | Silent (SNP) | VAF 47/310 reads (15%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.219G>A p.A73= | Silent (SNP) | VAF 123/507 reads (24%) | catalogued as rs773426752; called by muse, mutect2, varscan2
- SH2D3A | c.657C>T p.F219= | Silent (SNP) | VAF 71/457 reads (16%) | catalogued as COSV55587521, COSV55588199; called by muse, mutect2, varscan2
- SLC15A4 | c.378C>T p.P126= | Silent (SNP) | VAF 151/631 reads (24%) | catalogued as rs1242161004; called by muse, mutect2, varscan2
- SV2A | c.183C>A p.P61= | Silent (SNP) | VAF 24/736 reads (3%) | called by muse, mutect2
- THSD7A | c.507G>A p.A169= | Silent (SNP) | VAF 70/354 reads (20%) | catalogued as rs867019373, COSV101448676; called by muse, mutect2, varscan2
- VILL | c.2454G>A p.R818= | Silent (SNP) | VAF 19/339 reads (6%) | called by muse, mutect2
- NRXN2 | c.3403+5462C>T | Intron (SNP) | VAF 153/978 reads (16%) | catalogued as rs1056453515; called by muse, mutect2, varscan2
